Somatic mutation profile of tumor specimen TCGA-13-0890-01A (aliquot TCGA-13-0890-01A-01W-0421-09) from TCGA case TCGA-13-0890, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,770 days).
Specimen TCGA-13-0890-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4707929b-d612-427d-89c3-3d65b98e3fac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0890-10A (Blood Derived Normal), aliquot TCGA-13-0890-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6b2022d-6cb0-4ebd-96a7-81ee7259aea0

The open-access MAF lists 71 somatic variants for this specimen: 58 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 11, Frame Shift Del 3, Splice Site 2, In Frame Del 2, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.3688del p.S1230Lfs*9 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs878853573; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS20 | c.1625A>C p.H542P | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV67136986; called by muse, mutect2, varscan2
- ADCK1 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99451537; called by muse, mutect2
- AKAP1 | c.2444T>A p.V815D | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61805791; called by muse, mutect2, varscan2
- ARHGEF10 | c.567A>C p.E189D (on ENST00000398564; = p.E164D on NM_014629.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.081); catalogued as COSV50668023; called by muse, mutect2, varscan2
- ARHGEF15 | c.2261A>G p.E754G | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV62726022; called by muse, mutect2, varscan2
- ATG16L1 | c.642G>T p.R214S | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV61468039, COSV61468154; called by muse, mutect2
- ATP2A1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs768227607, COSV63921956; called by muse, mutect2, varscan2
- AWAT1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs1193140346, COSV65738124, COSV65738782; called by muse, mutect2
- BCORL1 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV54403715; called by muse, mutect2, varscan2
- BOLL | c.499T>G p.S167A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV56576481; called by muse, mutect2, varscan2
- CBLIF | c.457A>T p.I153L | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV57240038; called by muse, mutect2, varscan2
- CEP19 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.463); catalogued as COSV99582408; called by muse, mutect2, varscan2
- CLTRN | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as COSV66712311; called by mutect2, varscan2
- EMSY | c.787T>C p.F263L | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58264459; called by muse, mutect2, varscan2
- FBH1 | c.1732A>T p.I578F (on ENST00000362091 / NM_178150.3; = p.I629F on NM_032807.4) | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs765708557, COSV62984030; called by muse, mutect2, varscan2
- GPR149 | c.802T>G p.S268A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV67669180; called by muse, mutect2, varscan2
- HRH4 | c.1073A>T p.Y358F | Missense Mutation (SNP) | VAF 151/565 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56929293; called by muse, mutect2, varscan2
- IFT172 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53137398; called by muse, mutect2, varscan2
- IGF2R | c.5845C>G p.R1949G | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV63631737; called by muse, mutect2, varscan2
- IMPDH1 | c.1464G>T p.K488N (on ENST00000470772 / NM_001142573.2; = p.K574N on NM_000883.4) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100118652; called by muse, mutect2
- INPP5F | c.3163G>T p.V1055L | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV62823063; called by muse, mutect2, varscan2
- KSR2 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs779209250, COSV100348449, COSV60399516; called by muse, mutect2
- LAMP3 | c.760-1G>C p.X254_splice | Splice Site (SNP) | VAF 118/403 reads (29%) | catalogued as COSV55616431; called by muse, mutect2, varscan2
- LYN | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV101319621, COSV70206227; called by muse, mutect2, varscan2
- MPHOSPH10 | c.2006A>G p.K669R | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV54916092; called by muse, mutect2, varscan2
- MTHFD1L | c.2247G>C p.M749I | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66226845; called by muse, mutect2, varscan2
- MTMR12 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); catalogued as COSV53782768, COSV53786660; called by muse, mutect2, varscan2
- MUC3A | c.8254C>A p.L2752I | Missense Mutation (SNP) | VAF 66/462 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.334); catalogued as rs746970474, COSV60222445; called by muse, mutect2
- NCOA3 | c.3593C>G p.P1198R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV59071851; called by muse, mutect2, varscan2
- NUP210L | c.2804A>C p.Q935P | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.374); catalogued as rs1266744764, COSV55154655; called by muse, mutect2, varscan2
- OBSCN | c.3574C>G p.Q1192E | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.6); catalogued as COSV52811895, COSV99472103; called by muse, mutect2, varscan2
- OVGP1 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63859678; called by muse, mutect2, varscan2
- PHF21B | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.37); catalogued as rs781571122, COSV57560962; called by muse, mutect2, varscan2
- PRC1 | c.1403C>G p.P468R | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as COSV62695062, COSV62696276; called by muse, mutect2, varscan2
- RELCH | c.869T>G p.L290* | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as COSV56890141; called by muse, mutect2, varscan2
- SENP6 | c.890C>G p.T297S | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59193354; called by muse, mutect2, varscan2
- SIK3 | c.2301A>C p.L767F (on ENST00000445177 / NM_001366686.2; = p.L725F on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV52621236; called by muse, mutect2, varscan2
- SLC12A8 | c.2133G>C p.M711I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.02); catalogued as COSV100102242; called by muse, mutect2
- SORBS2 | c.2816A>G p.E939G (on ENST00000284776 / NM_021069.5; = p.E505G on NM_003603.6) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53010991; called by muse, mutect2, varscan2
- SPOCD1 | c.2819C>A p.T940N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99929761; called by muse, mutect2, varscan2
- STAB2 | c.155T>A p.V52D | Missense Mutation (SNP) | VAF 85/322 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV66344495; called by muse, mutect2, varscan2
- STAT3 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99232699; called by muse, mutect2, varscan2
- SYT17 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 109/283 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV62547629; called by muse, mutect2, varscan2
- TAF1 | c.4188C>G p.D1396E (on ENST00000373790 / NM_138923.4; = p.D1417E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52121784; called by muse, mutect2, varscan2
- TBC1D5 | c.1430G>C p.S477T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV53766783, COSV99511835; called by muse, mutect2, varscan2
- TENM2 | c.2688G>T p.W896C (on ENST00000518659 / NM_001122679.2; = p.W664C on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV69138171, COSV69143831; called by muse, mutect2, varscan2
- TMEM94 | c.1491dup p.E498Rfs*30 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | catalogued as rs749805153; called by pindel, varscan2
- TNIK | c.1371G>T p.Q457H | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs916652428, COSV52691601; called by muse, mutect2, varscan2
- TSR1 | c.1152G>C p.K384N | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52160733; called by muse, mutect2, varscan2
- UMPS | c.75C>G p.D25E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99228945; called by muse, mutect2, varscan2
- WAC | c.1437+1G>T p.X479_splice | Splice Site (SNP) | VAF 49/247 reads (20%) | catalogued as COSV100610959, COSV61569127, COSV61569197; called by muse, mutect2, varscan2
- ATG16L1 | c.643A>T p.R215W | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSTF3 | c.302_312del p.W101Sfs*10 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- EVC2 | c.1906_1917del p.D636_E639del | In Frame Del (DEL) | VAF 20/78 reads (26%) | called by pindel, varscan2
- GLP2R | c.454_465del p.I152_D155del | In Frame Del (DEL) | VAF 34/218 reads (16%) | called by mutect2, pindel, varscan2
- MTCL1 | c.1316_1322del p.L439Rfs*20 (on ENST00000306329 / NM_001378206.1; = p.L79Rfs*20 on NM_015210.4) | Frame Shift Del (DEL) | VAF 46/238 reads (19%) | called by mutect2, pindel, varscan2
- PLEKHS1 | c.849C>A p.H283Q (on ENST00000369310 / NM_182601.1; = p.H289Q on NM_024889.5) | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); called by muse, mutect2
- AURKA | c.795A>G p.G265= | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as COSV57169717; called by muse, mutect2, varscan2
- DCTN1 | c.1356G>A p.E452= | Silent (SNP) | VAF 64/572 reads (11%) | catalogued as rs200138600, COSV100720923; called by muse, mutect2
- GIT1 | c.1626C>T p.D542= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99838146; called by muse, mutect2
- MYT1 | c.1509G>A p.T503= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as rs775580157, COSV60511211; called by muse, mutect2, varscan2
- NUP210L | c.1200A>G p.T400= | Silent (SNP) | VAF 64/321 reads (20%) | catalogued as COSV55154670; called by muse, mutect2, varscan2
- OR8B4 | c.441C>G p.S147= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as COSV100635803; called by muse, mutect2
- PIK3CA | c.1530C>T p.H510= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as rs200934230, COSV55946740; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTH | c.330T>C p.T110= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV56378833; called by muse, mutect2, varscan2
- STAG3 | c.1323C>A p.A441= | Silent (SNP) | VAF 48/187 reads (26%) | catalogued as COSV57933710; called by muse, mutect2, varscan2
- TTN | c.53439C>T p.S17813= (on ENST00000591111; = p.S10389= on NM_003319.4) | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as rs374998127; ClinVar: likely benign; called by muse, mutect2
- VRTN | c.2022C>T p.F674= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV56441042; called by muse, mutect2
- AL353804.6 | chrX:73829198 G>T | 3'Flank (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- OR2W5 | n.639C>A | RNA (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
